Gene-level copy-number profile of tumor specimen TCGA-73-4670-01A from TCGA case TCGA-73-4670, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 69.9 years (25,526 days).
Specimen TCGA-73-4670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.211a8ccf-09a6-42df-b17b-04f738f53748.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-4670-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84a4044e-67f7-4a5c-9c03-a80b1db9f40b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 1,360; copy number 2: 22,124; copy number 3: 18,867; copy number 4: 12,724; copy number 5: 3,420; copy number 6: 1,210; copy number 7: 17; copy number 8: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-4670-01A-01D-1204-01): tumor purity 0.62, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,321,300–26,118,408, 60 genes (within-gene range 0–4): IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:68,705,240–69,009,176, 4 genes (within-gene range 0–2): PIP5K1B, FAM122A, AL354794.2, AL354794.1.
- chr17:8,729,935–9,892,099, 28 genes (within-gene range 0–2): CCDC42, SPDYE4, MFSD6L, PIK3R6, PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,649 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,123,471–245,134,090, 2 genes, copy number 8: AL589763.1, RNU1-132P.
- chr2:45,388,680–45,612,165, 2 genes, copy number 5 (within-gene range 3–5): SRBD1, RN7SL414P.
- chr2:45,674,701–45,675,476, 1 gene, copy number 5: PRKCE-AS1.
- chr5:7,924,292–8,366,437, 7 genes, copy number 6 (within-gene range 4–6): AC025174.1, RNU1-76P, AC116361.1, AC091941.1, AC091912.2, AC091912.1, AC091912.3.
- chr5:19,471,296–27,121,150, 72 genes, copy number 5–7 (broad region; genes not listed).
- chr5:28,548,135–39,721,513, 186 genes, copy number 6 (broad region; genes not listed).
- chr6:167,607–58,438,364, 1,527 genes, copy number 5 (broad region; genes not listed).
- chr7:6,329,411–6,753,862, 18 genes, copy number 6: FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–7 (broad region; genes not listed).
- chr11:102,681,310–102,843,609, 10 genes, copy number 5: AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3.
- chr12:66,767–34,249,958, 850 genes, copy number 5–6 (broad region; genes not listed).
- chr12:46,358,188–46,876,784, 10 genes, copy number 6: SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:50,953,922–50,970,506, 1 gene, copy number 6 (within-gene range 4–6): HIGD1C.
- chr12:50,979,401–60,269,686, 424 genes, copy number 6 (broad region; genes not listed).
- chr22:33,704,786–33,922,766, 5 genes, copy number 6: SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1.

Autosomal genes at a single copy (total copy number 1): 1,360. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
